Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XD, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XD-01A (Primary Tumor).

[page 1 of 2]
105-0-3

carcinoma, infiltrating duct, nos 8500/3

site, breast, nos C50.9 m 4/12/11

page 1 / 2

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Examination No.:

Patient: XXX

PESEL: XXX

Age: Gender: F

Material: 1. Multiple organ resection – left breast with axillary tissues

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: upto 8 working days

Clinical diagnosis: Cancer of the left breast.

Qual/Synchronous Primary	Noted	X
Reviewer Initials	Date Submitted: 4/12/11	

Examination performed on:

Macroscopic description:

Left breast sized 21 x 18 x 3 cm removed along with axillary tissues sized 10 x 5 x 2 cm and a 15 x 6 cm skin flap. Weight 520 g. Tumour sized 1.9 x 1.6 x 1.7 cm in the middle part, 1.5 cm from the upper boundary, 1.6 cm from the base and 0 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum – NHG2 (2+3+2/10 mitoses/10 HPF - visual area: 0.55mm).

Foci of carcinoma ductale in situ (DCIS) found within the tumour (solid and cribrate type, with medium nuclear atypia, without necrosis and with calcifications of below 5% of the tumour).

Infiltratio carcinomatosa mamillae.

Focus of carcinoma ductale invasivum found in the glandular tissue (inner lower quadrant – diameter 0.1 cm).

Also showing also lesions of the type mastopathia fibrosa et cystica, hyperplasia ductalis simplex (UDH).

AXILLARY LYMPH NODES:

Metastases carcinomatosa in lymphonodis (No VI/XVIII).

Infiltratio capsulae lymphonodi.

Preliminary result:

Final response to be given after whole of the material is analysed.

Compliance validated by: I

Examination performed on: .

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei. Progesterone receptors found in over 75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by:

Examination performed on:

[page 2 of 2]
Examination: Histopathological examination

page 2 / 2

Examination No.:

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on:

Histopathological diagnosis:

Carcinoma ductale invasivum bifocal et ductale in situ mammae sinistrae.

Invasive ductal bifocal carcinoma and ductal in situ carcinoma of the left breast.

Metastases carcinomatosae in lymphonodis axillae (No VI/XVIII) (NHG2, pT1c, pN2a).

Cancer Metastases in axillary lymph nodes.

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 813c57a9-3c45-4d81-bd6c-ade9679ce4ab (TCGA-D8-A1XD.D5614445-4EBF-4050-8FC6-D34D5CAADD82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).